Somatic mutation profile of tumor specimen TCGA-QR-A6ZZ-01A (aliquot TCGA-QR-A6ZZ-01A-11D-A35D-08) from TCGA case TCGA-QR-A6ZZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 30.3 years (11,075 days).
Specimen TCGA-QR-A6ZZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dda66353-3834-4ba2-93b6-b45d36ba988d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6ZZ-10A (Blood Derived Normal), aliquot TCGA-QR-A6ZZ-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/466cee3b-666b-4ec2-82e5-96b7f147a3cb

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs1430324218, COSV66578629; called by muse, mutect2
- PCDHB4 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.341); catalogued as COSV52027047; called by muse, mutect2, varscan2
- PRMT9 | c.1723G>A p.V575I | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1415017824, COSV100482153; called by muse, mutect2
- VEZT | c.476T>G p.M159R | Missense Mutation (SNP) | VAF 102/218 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.5); catalogued as rs1278010609; called by muse, mutect2, varscan2
- ACACA | c.1037T>C p.M346T | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- C14orf28 | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CFAP47 | c.2143T>A p.S715T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- KDM5C | c.1759A>G p.N587D | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- OR4F6 | c.382A>T p.K128* | Nonsense Mutation (SNP) | VAF 51/198 reads (26%) | called by muse, mutect2, varscan2
- SPATA6L | c.998T>G p.F333C (on ENST00000461761 / NM_001353484.2; = p.F275C on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PC | c.375G>A p.A125= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs775684836; called by muse, mutect2, varscan2
